Gene-level copy-number profile of tumor specimen TCGA-VR-A8ER-01A from TCGA case TCGA-VR-A8ER, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 54.6 years (19,951 days).
Specimen TCGA-VR-A8ER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ee52b54e-d9fd-46a5-8137-6f390f75b26a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8ER-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/86522999-c110-4b73-ba23-c1e9166965ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 16,260; copy number 2: 33,226; copy number 3: 7,703; copy number 4: 266; copy number 5: 1,252; copy number 6: 616; copy number 7: 311; copy number 8: 17; copy number 9: 19; copy number 10: 59; copy number 11: 31; copy number 14: 30; copy number 16: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8ER-01A-11D-A36I-01): tumor purity 0.65, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:21,304,468–21,523,709, 3 genes: AC110296.1, MIR7978, AC096576.7.
- chr14:31,925,801–32,882,830, 17 genes: AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,337 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,940,550–16,974,497, 19 genes, copy number 5: MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866.
- chr2:171,783,405–172,736,206, 20 genes, copy number 10 (within-gene range 2–10): SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2.
- chr2:180,473,137–181,409,321, 11 genes, copy number 6: AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437.
- chr3:8,733,802–10,321,112, 61 genes, copy number 5–8 (broad region; genes not listed).
- chr3:10,330,229–10,330,285, 1 gene, copy number 8: MIR378B.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–7 (broad region; genes not listed).
- chr8:31,497,423–39,838,289, 137 genes, copy number 5–7 (broad region; genes not listed).
- chr11:28,477,481–31,432,835, 31 genes, copy number 6–14 (within-gene range 4–14): MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24.
- chr11:69,294,151–69,367,726, 1 gene, copy number 14 (within-gene range 3–14): MYEOV.
- chr11:69,371,463–71,252,577, 44 genes, copy number 11–14: AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr14:25,124,467–31,861,224, 86 genes, copy number 7 (within-gene range 0–7) (broad region; genes not listed).
- chr14:32,934,396–40,905,513, 126 genes, copy number 7–16 (within-gene range 0–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,845. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
